Gene-level copy-number profile of tumor specimen C3L-03727-01 from CPTAC case C3L-03727, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.4 years (26,097 days).
Specimen C3L-03727-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0e72471e-cb88-4577-825b-c7da8d77fd49.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03727-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/a12d766c-7e79-40ac-a8ef-1003a409f262

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 5,208; copy number 2: 45,924; copy number 3: 7,120; copy number 4: 5; copy number 14: 7; copy number 35: 3; copy number 40: 1; copy number 41: 64; copy number 43: 2.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene: AC010983.1.
- chr6:61,630,233–61,681,049, 1 gene (within-gene range 0–2): KHDRBS2-OT1.
- chr9:21,638,285–23,438,700, 23 genes (within-gene range 0–1): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:24,542,952–27,944,497, 34 genes: IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1.
- chr11:87,847,259–88,045,608, 2 genes (within-gene range 0–1): AP000676.5, AP000676.4.
- chr16:35,912,120–35,912,516, 1 gene: PPP1R1AP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 77 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,377,850–204,562,521, 7 genes, copy number 14: AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74.
- chr7:44,125,752–44,198,170, 3 genes, copy number 35: RNA5SP230, MYL7, GCK.
- chr7:45,574,140–45,723,116, 1 gene, copy number 40: ADCY1.
- chr7:49,230,137–49,259,846, 2 genes, copy number 43: AC091730.1, DDX43P2.
- chr7:53,862,233–56,365,270, 64 genes, copy number 41 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,096. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
